Gene-level copy-number profile of tumor specimen TCGA-BR-7715-01A from TCGA case TCGA-BR-7715, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 65.3 years (23,861 days).
Specimen TCGA-BR-7715-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.40b3f896-3f24-40fd-8e25-9079e2fb7389.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-7715-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d85e6603-868b-49eb-9979-1c6ba8c4d745

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 9,936; copy number 2: 28,828; copy number 3: 17,419; copy number 4: 1,940; copy number 5: 1,519; copy number 6: 5; copy number 7: 11; copy number 8: 21; copy number 10: 110; copy number 16: 8; copy number 17: 11; copy number 19: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-7715-01A-11D-2052-01): tumor purity 0.67, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:145,337,932–145,381,670, 1 gene: AC137770.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,695 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:157,929,071–158,094,763, 1 gene, copy number 5 (within-gene range 3–5): AC084740.1.
- chr4:158,109,500–158,111,931, 2 genes, copy number 5: AC098679.2, AC098679.3.
- chr8:52,110,839–52,460,959, 1 gene, copy number 6 (within-gene range 4–6): ST18.
- chr8:52,294,455–52,313,500, 2 genes, copy number 6: AC103831.1, RPL34P17.
- chr8:120,761,253–121,119,754, 3 genes, copy number 5 (within-gene range 4–5): AC104958.1, AC104958.2, AC068413.1.
- chr8:127,072,694–127,227,541, 1 gene, copy number 7 (within-gene range 4–7): CASC19.
- chr8:127,253,213–127,742,951, 9 genes, copy number 7: AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,796,028, 1 gene, copy number 7: MIR1204.
- chr17:39,401,793–42,025,644, 166 genes, copy number 5–10 (broad region; genes not listed).
- chr17:65,457,541–65,458,408, 1 gene, copy number 5: LINC02563.
- chr19:27,793,431–27,984,984, 1 gene, copy number 16 (within-gene range 2–16): AC006504.5.
- chr19:27,849,635–30,016,612, 49 genes, copy number 8–19 (within-gene range 1–19): AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,533. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
